Gene-level copy-number profile of tumor specimen ALCH-B34K-TTP1-A from ALCHEMIST case ALCH-B34K, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.9 years (25,544 days).
Specimen ALCH-B34K-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 34502191-c09f-4c34-ae6e-4aaff687ab1e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B34K-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,238 have no estimate.
https://portal.gdc.cancer.gov/files/29b3b0f6-6aef-4b67-864c-38d9b06bfe53

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 135; copy number 2: 53,072; copy number 3: 5,163; copy number 4: 6; copy number 5: 9.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 9 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr19:30,028,741–30,038,181, 3 genes, copy number 5: AC008507.2, TAF9P3, AC008507.1.
- chr22:18,178,038–18,391,105, 4 genes, copy number 5: FAM230D, GGTLC5P, FAM230J, AC011718.1.
- chr22:21,300,990–21,325,042, 2 genes, copy number 5 (within-gene range 3–5): FAM230H, AP000552.2.

Autosomal genes at a single copy (total copy number 1): 135. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
